ALCHEMIST case ALCH-ABEF — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/2718e54a-a8aa-4ca3-8708-adfa40ebac5c

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 65.5 years (23,940 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-ABEF-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-ABEF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-ABEF-TTP1-A-1-0-S2: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 70; Percent normal cells: 5; Percent necrosis: 20; Percent stromal cells: 20; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 40; Percent neutrophil infiltration: 10.
